Somatic mutation profile of tumor specimen MP2PRT-PAPYPB-TMP1-A (aliquot MP2PRT-PAPYPB-TMP1-A-1-0-D-A83B-36) from MP2PRT case MP2PRT-PAPYPB, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.6 years (2,060 days).
Specimen MP2PRT-PAPYPB-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3698861b-f136-4b94-9b52-40b9a2b98c9f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPYPB-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPYPB-NB1-A-1-0-D-A83B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f79aeda7-e75a-4c4d-b955-ba15819fc1bf

The open-access MAF lists 7 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 6, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC011462.1 | c.847G>A p.G283S | Missense Mutation (SNP) | VAF 49/894 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.55); catalogued as rs137852874, CM984176; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 73/468 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- BRINP2 | c.1445C>T p.P482L | Missense Mutation (SNP) | VAF 137/639 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as rs143438287, COSV100838156; called by muse, mutect2, varscan2
- NPFFR2 | c.1327C>T p.R443C | Missense Mutation (SNP) | VAF 31/544 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs141913034, COSV58154601; called by muse, mutect2
- SEMA6B | c.2455C>T p.R819W | Missense Mutation (SNP) | VAF 56/1080 reads (5%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.249); catalogued as rs1199714131; called by muse, mutect2
- SLC24A3 | c.245G>A p.R82Q | Missense Mutation (SNP) | VAF 89/378 reads (24%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs376513919; called by muse, mutect2, varscan2
- SIPA1L3 | c.1515G>A p.Q505= | Silent (SNP) | VAF 111/376 reads (30%) | catalogued as COSV99727851; called by muse, mutect2, varscan2
